Surgical pathology report (de-identified scan), TCGA case TCGA-4R-AA8I, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Duke University, specimen TCGA-4R-AA8I-01A (Primary Tumor).

[page 1 of 3]
Results

Surgical Pathology

Result Data

ACCESSION

Entry Date

ICD O 3
Carcinoma, Hepatocellular NOS 8170/3
Site: Liver C22.0
7/6/13/14

Component Results

Component	Lab
Clinical History	Unknown
Liver mass	
Gross Examination	Unknown

A. "Partial left liver resection", received fresh for frozen section and placed in formalin on [REDACTED] is an 84 gm, 12 x 5.8 x 3 cm portion of liver. The resection margin is inked black. On sectioning there is a 2.8 x 2.6 x 2.4 cm firm, tan-green, focally hemorrhagic, well circumscribed nodule. It is 0.8 cm from the resection margin and 0.1 cm from the capsule. The remaining parenchyma is tan and cirrhotic. The liver capsule is multinodular with fibrous bands. A representative section was submitted as frozen section AF1, transferred to block A7.

BLOCK SUMMARY:

- A1-A5-representative nodule (50%)
- A1-closest approach to capsule
- A2-closest approach to resection margin
- A6-representative of cirrhotic parenchyma.
- A7-frozen section AF1 remnant (please note submitted in block A7, not A1)

Intraoperative Consultation

Unknown

- A. "Partial left liver resection": AF1 (representative of nodule)-hepatocellular lesion consistent with hepatocellular carcinoma. (Dr. [REDACTED]).

Microscopic Examination

Unknown

Special stains are performed on block A3. The reticulin stain confirms loss of reticulin meshwork in the hepatocellular carcinoma. The tumor displays focal pseudoglandular growth pattern. The mucicarmine stain is negative.

In the background uninvolved liver, the trichrome and the reticulin special stains confirm the established cirrhosis. The portal tracts and the fibrous septa contain mild to moderate mononuclear inflammatory infiltrate. There is mild bile ductular proliferation, but the native bile ducts are intact. The parenchyma within regenerative nodules exhibits occasional ballooned hepatocytes with poorly-formed Mallory bodies. Patchy pericellular sinusoidal fibrosis is present within the regenerative nodules. The copper stain highlights mild copper deposit in periportal/periseptal hepatocytes. The PASD stain reveals PAS positive, diastase resistant, granules in periportal/periseptal hepatocytes. The iron stain is negative.

Pathologic Stage

Unknown

PATHOLOGIC STAGE (AJCC 7th Edition): pT2 pNX pMX

NOTE: Information on pathology stage and the operative procedure is transmitted to this Institution's Cancer Registry as required for accreditation by the Commission on Cancer. Pathology stage is based solely upon the current tissue specimen being evaluated, and does not incorporate information on any specimens submitted separately to our Cytology section,

[page 2 of 3]
[REDACTED]

past pathology information, imaging studies, or clinical or operative findings. Pathology stage is only a component to be considered in determining the clinical stage, and should not be confused with nor substituted for it. The exact operative procedure is available in the surgeon's operative report.

Diagnosis Unknown

A. "LIVER, LEFT LOBE" (PARTIAL LIVER RESECTION):

HEPATOCELLULAR CARCINOMA

Histologic type: HEPATOCELLULAR CARCINOMA.

Histologic grade: MODERATELY DIFFERENTIATED (GRADE 2).

Tumor Size: 2.8 x 2.6 x 2.4 CM.

Tumor Focality: SOLITARY (LEFT LIVER LOBE).

Tumor Extension: TUMOR CONFINED TO THE LIVER.

Margins: NEGATIVE.

Distance to closest margin: PARENCHYMAL MARGIN (0.8 CM).

Vascular invasion Major vascular invasion: ABSENT.
Microvascular invasion: PRESENT

Perineural Invasion: NEGATIVE.

Lymphatic Invasion: NEGATIVE

Regional Lymph Nodes: NOT SAMPLED.

Additional findings: CIRRHOSIS.

SEE COMMENT.

COMMENT: The uninvolved liver shows established cirrhosis. The presence of steatosis, occasional ballooned hepatocytes, and patchy pericellular sinusoidal fibrosis suggests steatohepatitis. The result of PASD and copper stains are not specific, however, the possibility of Wilson's disease and alpha-1-antitrypsin deficiency needs to be clinically excluded.

Dr. [REDACTED] has reviewed case and confirms the presence of microvascular invasion.
Comment:

I certify that I personally conducted the diagnostic evaluation of the above specimen(s) and have rendered the above diagnosis(es).

Dr. [REDACTED] M.D.

Electronically signed: [REDACTED]

Lab and Collection

Surgical Pathology on [REDACTED]

Result Information

Abnormality	Status	Priority	Source
	Final result [REDACTED]	Routine	

Authorizing Provider Information

Name: [REDACTED] MD	Fax: [REDACTED]
Phone: [REDACTED]	Pager: [REDACTED]

Surgical Pathology (Order

[REDACTED] Authorizing: [REDACTED] MD

Date: [REDACTED]

[page 3 of 3]
Pathology and Cytology
Order: [REDACTED]

Department: [REDACTED]

Released By:

Order Information

Order Date/Time	Release Date/Time	Start Date/Time	End Date/Time
[REDACTED]	[REDACTED]	[REDACTED]	[REDACTED]

Order Details

Frequency	Duration	Priority
Once	1 occurrence	Routine

Encounter

[View Encounter](#)

Reprint Requisition

Surgical Pathology (Order # [REDACTED] on [REDACTED])

Original Order

Ordered On [REDACTED] Ordered By [REDACTED]

Collection Information

Collection Date
[REDACTED]
Resulting Agency

Order Provider Info

	Office phone	Pager/beeper	E-mail
Ordering User	[REDACTED]	[REDACTED]	[REDACTED]
Authorizing Provider	[REDACTED]	[REDACTED]	[REDACTED]

Order-Level Documents:

There are no order-level documents.

No order transmittal information available.

Order may not have completed order transmittal.

Prior Malignancy History	hand call TX	/

Source: NCI Genomic Data Commons file 20980e05-8180-4883-97ec-fd7b1026ec56 (TCGA-4R-AA8I.1898901D-903B-48F4-B378-41144929245D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).